Somatic mutation profile of tumor specimen 0DJTFW from CCDI case PBBXDB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,128 days).
Specimen 0DJTFW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50238f16-fdf8-45a3-9ee8-a2e2d65bb796.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJTG2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9010298e-e5ec-440f-b68f-c6831f95489e

The open-access MAF lists 43 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 9, Intron 4, Splice Site 2, 3'UTR 2, 5'UTR 2, Nonsense Mutation 2, Frame Shift Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 281/737 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.6852_6855del p.Y2285Tfs*5 (on ENST00000358273 / NM_001042492.3; = p.Y2264Tfs*5 on NM_000267.3) | Frame Shift Del (DEL) | VAF 822/914 reads (90%) | catalogued as rs1555535032; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 654/681 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30B | c.894G>T p.L298F | Missense Mutation (SNP) | VAF 347/469 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV100746868; called by muse, mutect2, varscan2
- CYP2C9 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 184/752 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs748165211, COSV99583055; called by muse, mutect2, varscan2
- PIK3CA | c.813+1G>T p.X271_splice | Splice Site (SNP) | VAF 674/926 reads (73%) | catalogued as COSV55875051; called by mutect2, varscan2
- PNPLA2 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 303/545 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs1349259959; called by muse, mutect2, varscan2
- SCAI | c.1523G>A p.R508Q (on ENST00000336505 / NM_001144877.3; = p.R531Q on NM_173690.5) | Missense Mutation (SNP) | VAF 88/1877 reads (5%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.489); catalogued as rs1037274982, COSV57176079, COSV57176202; called by muse, mutect2
- SPATA31A3 | c.3380G>A p.G1127E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs1218083664; called by mutect2, varscan2
- ABCA1 | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 237/1493 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATRX | c.5892_5893insCA p.G1965Qfs*18 | Frame Shift Ins (INS) | VAF 275/408 reads (67%) | called by mutect2, pindel, varscan2
- FFAR3 | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 146/580 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2
- FOXA1 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 40/646 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.435); called by muse, mutect2
- GAD1 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 294/673 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GIPC3 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 33/165 reads (20%) | called by muse, mutect2, varscan2
- HCN1 | c.1482G>T p.E494D | Missense Mutation (SNP) | VAF 284/983 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- MYH7 | c.1464C>G p.F488L | Missense Mutation (SNP) | VAF 363/1256 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYH7 | c.1175C>G p.S392* | Nonsense Mutation (SNP) | VAF 167/786 reads (21%) | called by muse, mutect2, varscan2
- NSFL1C | c.1055G>C p.S352T | Missense Mutation (SNP) | VAF 40/964 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.089); called by muse, mutect2
- OR2F1 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 515/1308 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKD2L1 | c.2192T>C p.V731A | Missense Mutation (SNP) | VAF 215/634 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SNAI2 | c.80-2A>G p.X27_splice | Splice Site (SNP) | VAF 233/990 reads (24%) | called by muse, mutect2, varscan2
- STAT4 | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 510/1061 reads (48%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- WASHC1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); called by mutect2, varscan2
- ZNF784 | c.641A>C p.H214P | Missense Mutation (SNP) | VAF 190/390 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ATL3 | c.912T>C p.S304= | Silent (SNP) | VAF 118/515 reads (23%) | called by muse, mutect2, varscan2
- CUBN | c.3711T>G p.T1237= | Silent (SNP) | VAF 586/1407 reads (42%) | called by muse, mutect2, varscan2
- GON4L | c.3789G>C p.P1263= | Silent (SNP) | VAF 56/998 reads (6%) | catalogued as rs675918; called by muse, mutect2
- IRAG2 | c.1764G>A p.Q588= | Silent (SNP) | VAF 428/477 reads (90%) | called by muse, mutect2, varscan2
- KLF13 | c.696C>T p.C232= | Silent (SNP) | VAF 90/242 reads (37%) | catalogued as rs1224099118, COSV56147170; called by muse, mutect2, varscan2
- NIBAN2 | c.1518G>A p.K506= | Silent (SNP) | VAF 106/758 reads (14%) | called by muse, mutect2, varscan2
- OR2F1 | c.840T>A p.I280= | Silent (SNP) | VAF 600/1536 reads (39%) | called by muse, mutect2, varscan2
- PJA1 | c.786C>T p.N262= | Silent (SNP) | VAF 26/251 reads (10%) | called by muse, mutect2, varscan2
- TLE1 | c.1902T>C p.G634= | Silent (SNP) | VAF 87/1610 reads (5%) | called by muse, mutect2
- AL132655.6 | chr20:58840347 G>A | 5'Flank (SNP) | VAF 538/867 reads (62%) | catalogued as COSV58332231; called by muse, mutect2, varscan2
- CBFA2T3 | c.1204-72G>A | Intron (SNP) | VAF 45/214 reads (21%) | catalogued as rs911827014; called by muse, mutect2, varscan2
- ERICH1 | c.-4C>T | 5'UTR (SNP) | VAF 218/779 reads (28%) | catalogued as rs947122024; called by muse, mutect2, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 9/240 reads (4%) | called by muse, mutect2
- HTN1 | c.*13T>A | 3'UTR (SNP) | VAF 229/918 reads (25%) | catalogued as COSV99887589; called by muse, mutect2, varscan2
- MEX3B | c.256+67dup | Intron (INS) | VAF 33/134 reads (25%) | called by mutect2, pindel, varscan2
- RMC1 | c.-45C>T | 5'UTR (SNP) | VAF 38/247 reads (15%) | called by muse, mutect2, varscan2
- TMEM203 | c.*51C>T | 3'UTR (SNP) | VAF 59/343 reads (17%) | catalogued as rs1448405687; called by muse, mutect2, varscan2
- TTC16 | c.1765-30C>T | Intron (SNP) | VAF 41/232 reads (18%) | called by muse, mutect2, varscan2
